FM case AD5863 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/474e84dc-a43a-4cd3-a60a-1c56db4f580d

Female, 42.0 years: Carcinoma, anaplastic, NOS (ICD-O-3 8021/3) of the thyroid gland; metastasis biopsied or resected from the thyroid gland. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
